Gene-level copy-number profile of tumor specimen TCGA-85-7950-01A from TCGA case TCGA-85-7950, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 46.5 years (16,975 days).
Specimen TCGA-85-7950-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.117362e6-bf46-498d-a0ef-66034eb1e05a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-7950-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f41d6947-7ef0-4c75-8d58-5dc3f3101927

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 8; copy number 2: 24,291; copy number 3: 14,739; copy number 4: 15,006; copy number 5: 3,703; copy number 6: 141; copy number 7: 1,794; copy number 8: 21; copy number 47: 73.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-7950-01A-11D-2183-01): tumor purity 0.52, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:86,756,601–86,932,825, 3 genes (within-gene range 0–2): BMPR1A, RPAP2P1, RNU1-19P.
- chr15:25,266,591–27,541,984, 34 genes (within-gene range 0–2): SNORD115-46, SNORD115-47, SNORD115-48, SNORD109B, UBE3A, AC100774.1, LINC02250, AC023449.1, ATP10A, RNA5SP390, MIR4715, AC016266.1, LINC02346, AC044913.2, AC044913.1, AC100836.1, LINC00929, AC012060.1, LINC02248, AC009878.2, GABRB3, AC009878.1, AC011196.1, AC135999.1, GABRA5, TVP23BP1, GABRG3, GABRG3-AS1, AC136896.1, RNA5SP391, SERPINE4P, AC144833.1, AC104002.1, AC104002.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,732 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–4,140,731, 71 genes, copy number 5 (broad region; genes not listed).
- chr2:241,315,100–242,160,153, 38 genes, copy number 5: SEPTIN2, AC104841.1, AC005104.1, FARP2, AC005104.2, MIR3133, KCTD5P1, STK25, BOK-AS1, BOK, AC133528.1, THAP4, RNA5SP122, ATG4B, DTYMK, ING5, AC114730.3, D2HGDH, AC114730.1, AC114730.2, GAL3ST2, AC131097.1, AC131097.2, NEU4, AC131097.3, PDCD1, RTP5, LINC01237, FAM240C, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2.
- chr3:86,481,943–88,950,928, 25 genes, copy number 5: LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2.
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 5–7 (broad region; genes not listed).
- chr4:189,659,605–190,092,279, 26 genes, copy number 6: LINC01262, AF250324.1, RNU1-51P, FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr6:60,719,222–60,942,327, 5 genes, copy number 5 (within-gene range 3–5): GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3.
- chr6:120,015,179–160,277,638, 626 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:40,900,016–43,674,591, 82 genes, copy number 8–47 (broad region; genes not listed).
- chr15:33,310,962–90,922,584, 1,498 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr15:93,177,269–101,933,350, 182 genes, copy number 5 (broad region; genes not listed).
- chr16:78,872,739–79,004,730, 5 genes, copy number 5: AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2.
- chr18:75,642,494–75,928,004, 4 genes, copy number 6: AC090338.1, LINC01898, AC021506.1, AC021506.2.
- chr19:94,062–20,809,995, 1,146 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr20:87,250–9,839,076, 224 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
